Somatic mutation profile of tumor specimen ALCH-AEYX-TTP1-A (aliquot ALCH-AEYX-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEYX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.1 years (26,697 days).
Specimen ALCH-AEYX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a706143-1ad1-4704-b00c-fc9af2635522.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEYX-NB1-A (Blood Derived Normal), aliquot ALCH-AEYX-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29ae979e-69db-473d-9e88-440f8da18305

The open-access MAF lists 180 somatic variants for this specimen: 122 protein-altering or splice-affecting, 35 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 35, Intron 13, Nonsense Mutation 9, RNA 7, Frame Shift Del 4, Frame Shift Ins 4, 3'UTR 2, Splice Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.6050C>A p.P2017Q | Missense Mutation (SNP) | VAF 112/755 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV66068949; called by muse, mutect2, varscan2
- AL445989.1 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 204/930 reads (22%) | SIFT tolerated, low confidence (0.21); catalogued as rs1199477033; called by muse, mutect2, varscan2
- AMPD1 | c.1997C>G p.P666R | Missense Mutation (SNP) | VAF 63/478 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62419663; called by muse, mutect2, varscan2
- ANKRD30A | c.1076G>T p.R359M (on ENST00000611781; = p.R303M on NM_052997.2) | Missense Mutation (SNP) | VAF 68/507 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV64603909; called by muse, mutect2, varscan2
- BLK | c.1184C>G p.A395G | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99377432; called by muse, mutect2, varscan2
- CBFA2T3 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1461949410, COSV51924355; called by muse, mutect2, varscan2
- CCDC102B | c.1088G>T p.W363L | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60151930, COSV99076762; called by muse, mutect2, varscan2
- CCDC168 | c.18205G>A p.V6069I | Missense Mutation (SNP) | VAF 58/411 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV99079842; called by muse, mutect2, varscan2
- CCDC178 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 85/600 reads (14%) | catalogued as COSV55783997; called by muse, mutect2, varscan2
- CFHR1 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 130/997 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100259044; called by muse, mutect2, varscan2
- CHRD | c.619C>A p.R207S | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs539389142, COSV99200215; called by muse, mutect2, varscan2
- CNTN4 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 109/585 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61880939; called by muse, mutect2, varscan2
- COL6A3 | c.8432G>T p.R2811L | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769656291, COSV55092223; called by muse, mutect2, varscan2
- CSF2RB | c.1314G>A p.S438= | Splice Region (SNP) | VAF 35/290 reads (12%) | catalogued as rs772189360, COSV53256569, COSV99453718; called by muse, mutect2, varscan2
- DCAF4L2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 59/438 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100151496; called by muse, mutect2, varscan2
- DES | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV64659780; called by muse, mutect2, varscan2
- DNPEP | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99815087; called by muse, mutect2
- DOCK1 | c.3330G>T p.M1110I | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs746002233; called by muse, mutect2, varscan2
- DRD5 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1560111103; called by muse, mutect2
- EHBP1L1 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as COSV57079663; called by muse, mutect2
- EML6 | c.3239A>G p.H1080R | Missense Mutation (SNP) | VAF 46/399 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1302302963; called by muse, mutect2, varscan2
- FASN | c.5364C>G p.N1788K | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60757129; called by muse, mutect2, varscan2
- FIBIN | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs144159497, COSV100590534; called by muse, mutect2, varscan2
- HRG | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 98/573 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs186238444; called by muse, mutect2, varscan2
- ISCU | c.451G>T p.A151S (on ENST00000311893 / NM_213595.4; = p.A126S on NM_014301.4) | Missense Mutation (SNP) | VAF 82/463 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV57809676; called by muse, mutect2, varscan2
- KCNB2 | c.920G>C p.R307P | Missense Mutation (SNP) | VAF 103/384 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73053136; called by muse, mutect2, varscan2
- KLHL11 | c.1421A>T p.Y474F | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.413); catalogued as rs782390236; called by muse, mutect2, varscan2
- LRRTM1 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.371); catalogued as rs1425239869; called by muse, mutect2
- MCF2L2 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 61/323 reads (19%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as COSV61062183; called by muse, mutect2, varscan2
- MS4A6A | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1217897913; called by muse, mutect2, varscan2
- NDN | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs1490061295; called by muse, mutect2, varscan2
- NLRP13 | c.644T>A p.L215Q | Missense Mutation (SNP) | VAF 205/621 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs775070712; called by muse, mutect2, varscan2
- OR2F2 | c.504G>T p.M168I | Missense Mutation (SNP) | VAF 69/458 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV68833021; called by muse, mutect2, varscan2
- PAX8 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as rs769138605; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRDM9 | c.1716G>T p.R572S | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs765865152, COSV99690565; called by muse, mutect2, varscan2
- PTPRC | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 75/569 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766855254; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV50252038; called by muse, mutect2, varscan2
- RYR3 | c.8197G>T p.G2733* (on ENST00000389232; = p.G2734* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 25/222 reads (11%) | catalogued as COSV66810648; called by muse, mutect2, varscan2
- SDK2 | c.1976G>C p.R659P | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs367622362; called by muse, mutect2, varscan2
- SP2 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as rs757345564; called by muse, mutect2, varscan2
- SPTAN1 | c.7182C>A p.F2394L | Missense Mutation (SNP) | VAF 19/450 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100823682; called by muse, mutect2
- TSSK1B | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1331491584; called by muse, mutect2, varscan2
- TTLL8 | c.2468G>T p.R823L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs996492869; called by muse, mutect2, varscan2
- WDR25 | c.1189G>C p.A397P | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58936367; called by muse, mutect2
- XKR5 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as rs1480903148, COSV101306688; called by muse, mutect2
- ZNF594 | c.1346G>C p.R449T | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.302); catalogued as COSV68386082; called by muse, mutect2, varscan2
- ZSCAN5A | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 147/417 reads (35%) | catalogued as COSV99570359; called by muse, mutect2, varscan2
- ACKR1 | c.620A>C p.Q207P | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2
- ACTG1 | c.248A>G p.E83G | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AHNAK2 | c.4745C>A p.P1582H | Missense Mutation (SNP) | VAF 61/366 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANGPT1 | c.1141dup p.E381Gfs*10 | Frame Shift Ins (INS) | VAF 37/259 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD34C | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- AP4E1 | c.2902A>T p.K968* | Nonsense Mutation (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2, varscan2
- APOBEC3A | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); called by muse, mutect2
- ARGFX | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, varscan2
- ATP11A | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 81/390 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- BIRC7 | c.89G>T p.C30F | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C11orf80 | c.571-1G>T p.X191_splice | Splice Site (SNP) | VAF 36/248 reads (15%) | called by muse, varscan2
- CACNA1C | c.5620T>A p.W1874R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1I | c.68C>A p.T23K | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CACNA2D4 | c.1550A>G p.K517R | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CHGA | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2W1 | c.1360dup p.Y454Lfs*48 | Frame Shift Ins (INS) | VAF 6/62 reads (10%) | called by mutect2, pindel
- FILIP1L | c.1031T>C p.L344S (on ENST00000354552 / NM_182909.3; = p.L104S on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/548 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FRAS1 | c.2540C>A p.P847H | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GABPA | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 29/326 reads (9%) | called by muse, mutect2, varscan2
- GAK | c.3461G>T p.S1154I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GET1-SH3BGR | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.372); called by muse, mutect2
- GIMAP1 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- GNPNAT1 | c.532A>T p.M178L | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.898); called by mutect2, varscan2
- GRN | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 59/380 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF3C4 | c.1597_1603del p.L533Sfs*3 | Frame Shift Del (DEL) | VAF 58/485 reads (12%) | called by mutect2, pindel, varscan2
- HMCN2 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IAPP | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 43/355 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- IGSF5 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- IMMP1L | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- INVS | c.215C>G p.A72G | Missense Mutation (SNP) | VAF 104/630 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- KLK15 | c.644G>C p.C215S | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2E | c.1241A>G p.N414S | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LARP4B | c.1965del p.R656Efs*97 | Frame Shift Del (DEL) | VAF 15/136 reads (11%) | called by mutect2, pindel
- LCT | c.3730G>C p.A1244P | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- LENG9 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NDUFV1 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52N1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 61/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR5T1 | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 81/598 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PCDHB1 | c.1603A>G p.T535A | Missense Mutation (SNP) | VAF 62/439 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHB10 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 64/496 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PCDHB12 | c.59del p.L20Cfs*16 | Frame Shift Del (DEL) | VAF 14/78 reads (18%) | called by pindel, varscan2
- PCYOX1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLA2R1 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); called by muse, varscan2
- PRKCE | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 38/257 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PTPRK | c.3848C>T p.P1283L (on ENST00000368215 / NM_001291984.2; = p.P1284L on NM_002844.4) | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- PYCR2 | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RPS4Y2 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- RYR2 | c.10171G>A p.E3391K | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- S100A16 | c.72dup p.K25* | Frame Shift Ins (INS) | VAF 37/355 reads (10%) | called by mutect2, pindel, varscan2
- SCG3 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 75/520 reads (14%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.1420A>G p.I474V (on ENST00000291707 / NM_053003.4; = p.I356V on NM_033329.2) | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, varscan2
- SLC7A2 | c.226G>T p.A76S (on ENST00000494857 / NM_001370338.1; = p.A116S on NM_003046.6) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLITRK1 | c.1070T>C p.M357T | Missense Mutation (SNP) | VAF 115/524 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SNTG1 | c.986C>A p.T329K | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SPACA9 | c.637C>G p.P213A | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.624); called by mutect2, varscan2
- TAF6L | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TAS1R1 | c.348del p.R117Efs*11 | Frame Shift Del (DEL) | VAF 23/204 reads (11%) | called by mutect2, pindel, varscan2
- TAS1R2 | c.397T>C p.S133P | Missense Mutation (SNP) | VAF 44/295 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TET3 | c.2410A>T p.K804* | Nonsense Mutation (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- TLN1 | c.1318G>T p.G440W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TLR10 | c.1838G>A p.C613Y | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM245 | c.1721A>T p.K574M | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRPM6 | c.2929A>G p.M977V | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- TTN | c.38411dup p.E12805Gfs*5 (on ENST00000591111; = p.E5381Gfs*5 on NM_003319.4) | Frame Shift Ins (INS) | VAF 107/813 reads (13%) | called by mutect2, pindel, varscan2
- USH2A | c.7252C>T p.Q2418* | Nonsense Mutation (SNP) | VAF 84/472 reads (18%) | called by muse, mutect2, varscan2
- USP42 | c.3268G>T p.E1090* | Nonsense Mutation (SNP) | VAF 23/111 reads (21%) | called by muse, mutect2, varscan2
- VPS9D1 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- WWP1 | c.1898A>T p.Y633F | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- YY1AP1 | c.1846G>A p.G616S (on ENST00000295566 / NM_139118.2; = p.G559S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF300 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF300 | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, varscan2
- ZNF354B | c.1733A>T p.Y578F | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF431 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF594 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- ZNF625 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 61/343 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCC12 | c.3921T>A p.T1307= | Silent (SNP) | VAF 27/290 reads (9%) | called by muse, mutect2
- ANO3 | c.339G>A p.T113= | Silent (SNP) | VAF 36/251 reads (14%) | catalogued as rs375037623, COSV56785062; called by muse, mutect2, varscan2
- APC2 | c.4422C>T p.S1474= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- CASC3 | c.1149A>T p.P383= | Silent (SNP) | VAF 40/261 reads (15%) | catalogued as rs751327157; called by muse, varscan2
- CDK3 | c.228C>T p.L76= | Silent (SNP) | VAF 32/199 reads (16%) | catalogued as COSV56906677; called by muse, mutect2, varscan2
- CELF6 | c.777G>A p.A259= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV54715318; called by muse, mutect2, varscan2
- DUOXA2 | c.474G>A p.A158= | Silent (SNP) | VAF 28/216 reads (13%) | catalogued as rs370659104, COSV50994501; called by muse, mutect2, varscan2
- DYNC1I2 | c.939C>G p.A313= | Silent (SNP) | VAF 37/359 reads (10%) | called by muse, mutect2, varscan2
- GIMAP1 | c.679C>T p.L227= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs1008284962; called by muse, mutect2, varscan2
- GPR137B | c.33C>T p.S11= | Silent (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2
- ITPR3 | c.1614G>A p.L538= | Silent (SNP) | VAF 22/185 reads (12%) | called by muse, mutect2, varscan2
- KDM3A | c.2034G>A p.R678= | Silent (SNP) | VAF 38/235 reads (16%) | catalogued as rs1365260060; called by muse, mutect2, varscan2
- LRP1B | c.11835A>C p.G3945= | Silent (SNP) | VAF 96/622 reads (15%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.124C>T p.L42= | Silent (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- MS4A2 | c.534C>T p.S178= | Silent (SNP) | VAF 79/581 reads (14%) | called by muse, mutect2, varscan2
- MYH8 | c.480C>A p.I160= | Silent (SNP) | VAF 87/598 reads (15%) | catalogued as COSV67970256; called by muse, mutect2, varscan2
- MYL3 | c.567G>T p.V189= | Silent (SNP) | VAF 67/343 reads (20%) | called by muse, mutect2, varscan2
- NRG2 | c.841C>A p.R281= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as COSV99179947; called by muse, mutect2, varscan2
- OR4D6 | c.666G>C p.L222= | Silent (SNP) | VAF 52/295 reads (18%) | called by muse, mutect2, varscan2
- OR5T1 | c.900C>T p.I300= | Silent (SNP) | VAF 56/358 reads (16%) | catalogued as COSV57302182; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.891G>T p.V297= (on ENST00000374531 / NM_001037293.2; = p.V329= on NM_053016.6) | Silent (SNP) | VAF 74/498 reads (15%) | called by muse, mutect2, varscan2
- PAQR8 | c.873C>T p.I291= | Silent (SNP) | VAF 53/286 reads (19%) | catalogued as rs369094262; called by muse, mutect2, varscan2
- PCDHGA3 | c.1902C>T p.D634= | Silent (SNP) | VAF 32/283 reads (11%) | called by muse, mutect2, varscan2
- RAG1 | c.2454G>C p.V818= | Silent (SNP) | VAF 99/781 reads (13%) | called by muse, mutect2, varscan2
- SDK2 | c.2466C>A p.G822= | Silent (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- SLC7A4 | c.1257G>T p.P419= | Silent (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- SORCS3 | c.2658G>T p.A886= | Silent (SNP) | VAF 50/386 reads (13%) | catalogued as COSV100863832, COSV63793931, COSV63794340; called by muse, mutect2, varscan2
- STAB1 | c.2313G>A p.S771= | Silent (SNP) | VAF 18/199 reads (9%) | catalogued as rs776999553, COSV58736158; called by muse, mutect2
- TANC1 | c.2916C>T p.L972= | Silent (SNP) | VAF 51/397 reads (13%) | called by muse, mutect2, varscan2
- TIGD4 | c.756T>C p.Y252= | Silent (SNP) | VAF 71/335 reads (21%) | catalogued as rs138357980; called by muse, mutect2, varscan2
- TPR | c.5148A>T p.T1716= | Silent (SNP) | VAF 33/220 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.10551G>T p.G3517= (on ENST00000591111; = p.G3471= on NM_003319.4) | Silent (SNP) | VAF 125/733 reads (17%) | called by muse, mutect2, varscan2
- UBR1 | c.1323T>C p.I441= | Silent (SNP) | VAF 24/882 reads (3%) | called by muse, mutect2
- UGT2B10 | c.1266A>T p.T422= | Silent (SNP) | VAF 66/486 reads (14%) | called by muse, mutect2, varscan2
- ZFHX4 | c.1083C>T p.R361= | Silent (SNP) | VAF 68/784 reads (9%) | catalogued as rs781179725; called by muse, mutect2
- AC093791.1 | n.365C>A | RNA (SNP) | VAF 40/408 reads (10%) | called by muse, mutect2, varscan2
- AMPD3 | c.1134+103G>T | Intron (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- AMPH | c.1183-1144A>T | Intron (SNP) | VAF 60/443 reads (14%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.872G>A | RNA (SNP) | VAF 9/144 reads (6%) | catalogued as rs1242479435; called by muse, mutect2
- C1orf229 | n.358T>C | RNA (SNP) | VAF 16/78 reads (21%) | catalogued as rs950693695; called by muse, mutect2, varscan2
- CCNB1IP1 | c.297+406T>A | Intron (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- CHIT1 | c.*646A>G | 3'UTR (SNP) | VAF 37/670 reads (6%) | called by muse, mutect2
- CIDEA | c.38+350C>G | Intron (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100255034; called by mutect2, varscan2
- CLN3 | c.890+47A>T | Intron (SNP) | VAF 55/271 reads (20%) | called by muse, mutect2, varscan2
- ELP6 | c.*42G>T | 3'UTR (SNP) | VAF 39/259 reads (15%) | called by muse, mutect2, varscan2
- GCNT2P1 | n.721A>T | RNA (SNP) | VAF 56/343 reads (16%) | called by muse, mutect2, varscan2
- LINC02118 | n.107G>A | RNA (SNP) | VAF 44/410 reads (11%) | catalogued as rs774142355; called by muse, mutect2, varscan2
- LSM8 | c.31+64G>T | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as COSV50800694; called by muse, varscan2
- MARCHF1 | c.-322-85598C>A | Intron (SNP) | VAF 105/651 reads (16%) | catalogued as COSV72280841; called by muse, mutect2, varscan2
- MEF2C | c.835-15T>C | Intron (SNP) | VAF 60/468 reads (13%) | called by muse, mutect2, varscan2
- MYH16 | n.4267C>A | RNA (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- NALCN | c.1765-4857T>G | Intron (SNP) | VAF 46/800 reads (6%) | catalogued as COSV51922869, COSV51925386, COSV51970703; called by muse, mutect2
- PHKB | c.3145-48C>T | Intron (SNP) | VAF 22/396 reads (6%) | called by muse, mutect2
- POMT1 | c.1432-30A>G | Intron (SNP) | VAF 23/215 reads (11%) | called by muse, mutect2, varscan2
- RGS11 | c.318+115C>T | Intron (SNP) | VAF 13/72 reads (18%) | catalogued as COSV51454295; called by muse, mutect2, varscan2
- SMG7 | c.2742+915del | Intron (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel
- SMPX | c.-62A>T | 5'UTR (SNP) | VAF 62/230 reads (27%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1442C>G | RNA (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
